FM case AD17439 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach.
https://portal.gdc.cancer.gov/cases/158f6368-6aee-4b28-9b66-90b1c6d06b96

Female, 54.0 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the stomach; metastasis biopsied or resected from the pleura. Tumor nuclei on the sequenced sample's slide: 15% (pathologist estimate recorded by GDC). Sample type: Metastatic.
